Gene-level copy-number profile of tumor specimen TCGA-BL-A13J-01B from TCGA case TCGA-BL-A13J, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Posterior wall of bladder; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 65.5 years (23,927 days).
Specimen TCGA-BL-A13J-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.cb14ec4c-1dcb-435b-b93e-65680a2ef496.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BL-A13J-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 358 have no estimate.
https://portal.gdc.cancer.gov/files/38167f7b-95fa-40d2-bcf7-5911ea681fef

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 920; copy number 1: 28,928; copy number 2: 28,306; copy number 3: 1,369; copy number 4: 329; copy number 5: 332; copy number 7: 78; copy number 9: 1; copy number 18: 2.
ABSOLUTE estimates for another vial of this sample (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BL-A13J-01A-11D-A273-01): tumor purity 0.56, ploidy 3.59, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 90 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,966,929–25,584,272, 30 genes: CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL357614.1, AL445623.2, SUMO2P2, AL445623.1, NOP56P2, ELAVL2, AL161628.1, AL365204.1, AL365204.2, AL365204.3, AL513317.1, IZUMO3, AL353811.1, RMRPP5, RN7SKP120, AL353730.1.
- chr15:60,215,537–60,223,272, 1 gene: AC037433.1.
- chr19:47,994,632–48,025,154, 1 gene (within-gene range 0–2): ELSPBP1.
- chr22:16,405,330–17,353,177, 56 genes: AC137499.1, PABPC1P9, SLC9B1P4, ACTR3BP6, CHEK2P4, AP000547.2, AP000547.1, KCNMB3P1, CCT8L2, AP000547.4, FABP5P11, TPTEP1, AP000547.3, AP000365.1, SLC25A15P5, PARP4P3, ANKRD62P1-PARP4P3, ANKRD62P1, AC005301.1, VWFP1, AC005301.2, LINC01665, XKR3, HSFY1P1, GPM6BP3, AC007064.4, AC007064.3, ZNF402P, AC007064.2, MTND1P17, AC007064.1, AC006548.1, IGKV1OR22-5, IGKV2OR22-4, IGKV2OR22-3, IGKV3OR22-2, IGKV1OR22-1, AC006548.3, GAB4, AC006548.2, VN1R9P, CECR7, AC006946.2, AC006946.3, IL17RA, AC006946.1, TMEM121B, LINC01664, HDHD5, HDHD5-AS1, ADA2, AC005300.1, FAM32BP, CECR3, CECR9, RN7SL843P.
- chr22:17,418,697–17,424,775, 2 genes: FO681548.1, CLCP1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 412 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:158,127,287–168,729,206, 321 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr1:186,375,838–194,198,708, 78 genes, copy number 7 (within-gene range 3–7) (broad region; genes not listed).
- chr15:69,278,328–69,461,806, 11 genes, copy number 5: AC026992.2, AC026992.1, PAQR5, AC027237.4, AC027237.3, Y_RNA, KIF23, AC027237.1, RPLP1, U3, AC027237.2.
- chr20:1,561,385–1,620,061, 2 genes, copy number 18 (within-gene range 2–18): SIRPB1, AL049634.3.

Autosomal genes at a single copy (total copy number 1): 26,818. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
